Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72Q, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72Q-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS C64.9
JW8/9/13

Diagnosis:

A: Kidney, left, partial nephrectomy

Procedure: Partial nephrectomy

Laterality: Left

Histologic tumor type/subtype: Chromophobe renal cell carcinoma

Sarcomatoid features: Not identified

Histologic grade (if applicable): Fuhrman grade 2

Tumor size (greatest dimension): 5.7 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: The capsule over the tumor is very attenuated (block A2). No definite invasion into perirenal adipose tissue seen

Gerota's fascia: Not identified

Venous (large vessel): not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): Negative

Renal capsular margin (partial nephrectomy only): Free of tumor but close, less than 0.1 mm

Paranephric adipose tissue margin (partial nephrectomy only): Negative

Lymph nodes: none submitted

Pathologic findings in non-neoplastic kidney: No significant pathologic abnormalities

AJCC Staging:

pT1b

pNX

[page 2 of 2]
This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old male with a left renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left renal mass." It holds a 50 gram partial nephrectomy specimen measuring 6.4 x 4.4 x 3.0 cm. A fairly well circumscribed mass is identified within the partial nephrectomy specimen measuring 5.7 x 2.2 x 1.9 cm. The capsule overlying the mass is inked black and the renal parenchymal margin is inked in blue. Sectioning through the tumor reveals a variegated cut surface with tan/white firm calcified areas admixed with hemorrhagic areas. The tumor appears to abut the blue inked parenchymal margin grossly.

Block summary:

A1-A4 - tumor with blue inked parenchymal margin

A5-A7 - additional sections of tumor including black inked capsule

A8 - additional sections of calcified tumor with blue inked parenchymal margin

Source: NCI Genomic Data Commons file c1c406f5-38df-4687-b01d-8e96716431a4 (TCGA-UW-A72Q.6523685F-8E71-4BC6-8402-F3FBD3332F32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).